Somatic mutation profile of tumor specimen TCGA-SB-A6J6-01A (aliquot TCGA-SB-A6J6-01A-11D-A435-10) from TCGA case TCGA-SB-A6J6, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 22.5 years (8,233 days).
Specimen TCGA-SB-A6J6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ae40ede-df1e-4ad4-8bda-e51a7872c74f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SB-A6J6-10A (Blood Derived Normal), aliquot TCGA-SB-A6J6-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b9ceb1d-486c-440e-b6ab-a7da84810a43

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Intron 2, Nonsense Mutation 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BIRC6 | c.8459C>G p.S2820* | Nonsense Mutation (SNP) | VAF 6/63 reads (10%) | catalogued as COSV70204499; called by muse, mutect2
- DNAJC12 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs769789184; called by muse, mutect2, varscan2
- POU4F2 | c.220A>T p.S74C | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); catalogued as COSV55586671; called by muse, mutect2, varscan2
- STK11IP | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs770509684; called by muse, mutect2
- THBS3 | c.1073T>C p.I358T | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs1448113899; called by muse, mutect2, varscan2
- ADGRB3 | c.1993C>A p.Q665K | Missense Mutation (SNP) | VAF 74/349 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- CDK14 | c.842A>T p.K281I (on ENST00000380050 / NM_001287135.2; = p.K263I on NM_012395.3) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CKAP4 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.279); called by muse, mutect2
- COG1 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DCHS1 | c.3541del p.V1181Cfs*56 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by mutect2, varscan2
- FOXA1 | c.1083C>A p.S361R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- JAK2 | c.2219G>T p.G740V | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEL1L | c.761C>G p.S254C | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2
- WDR87 | c.434T>C p.L145P | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FASTKD1 | c.1350C>T p.N450= | Silent (SNP) | VAF 41/326 reads (13%) | called by muse, mutect2, varscan2
- GFAP | c.810C>A p.R270= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- NYNRIN | c.1059G>A p.G353= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as rs776592865; called by muse, mutect2, varscan2
- ALMS1 | c.11548-41G>C | Intron (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- RBM3 | c.*23+52G>A | Intron (SNP) | VAF 15/51 reads (29%) | catalogued as rs781851358; called by muse, mutect2, varscan2
- RUFY3 | chr4:70793873 C>T | 3'Flank (SNP) | VAF 22/216 reads (10%) | catalogued as COSV56912667; called by muse, mutect2, varscan2
